Gene-level copy-number profile of tumor specimen TCGA-13-2059-01A from TCGA case TCGA-13-2059, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 50.5 years (18,449 days).
Specimen TCGA-13-2059-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.019358e7-9795-4e8f-9751-3dfffe99c5ab.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-2059-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b10748dd-a0c8-46f0-8fa4-886bcb8ae530

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 4,211; copy number 2: 18,713; copy number 3: 15,677; copy number 4: 11,958; copy number 5: 4,835; copy number 6: 2,616; copy number 7: 1,302; copy number 8: 443; copy number 9: 10; copy number 11: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-2059-01A-01D-1043-01): tumor purity 0.73, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:128,292,751–133,208,606, 45 genes (within-gene range 0–1): LINC02615, AC110609.1, AC078850.1, AC078850.2, JADRR, JADE1, SCLT1, AC093783.1, AC093826.1, C4orf33, CDRT15P11, ZSWIM5P3, AC105417.1, AC082650.1, AC082650.2, LINC02466, LINC02465, EEF1GP8, LINC02479, PGBD4P4, GAPDHP56, AC093831.2, AC093831.1, AC093902.1, AC025554.1, RNU6-224P, LINC02377, AC105424.1, RN7SL205P, SNHG27, SNORA70, AC107393.1, RPL7AP28, AC096711.2, AC093916.1, AC096711.1, ELL2P2, AC114741.1, LINC01256, AARS1P1, AC115622.1, AC110751.1, AC105383.1, R3HDM2P1, PCDH10.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,209 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,963,954–6,730,012, 40 genes, copy number 5: BX005132.1, LINC02781, LINC02782, AL139823.1, Z98259.3, Z98259.2, Z98259.1, Z97988.2, AL365255.1, Z97988.1, MIR4689, NPHP4, KCNAB2, CHD5, AL031847.1, RPL22, RNF207-AS1, RNF207, ICMT, LINC00337, HES3, GPR153, ACOT7, AL031848.2, HES2, ESPN, MIR4252, AL031848.1, TNFRSF25, PLEKHG5, NOL9, RNU6-731P, AL591866.1, TAS1R1, ZBTB48, KLHL21, PHF13, THAP3, DNAJC11, LINC01672.
- chr1:34,166,883–34,859,755, 10 genes, copy number 5 (within-gene range 4–5): C1orf94, AC115286.1, AC099565.1, MIR552, SMIM12, GJB5, GJB4, AL121988.1, GJB3, GJA4.
- chr1:40,300,489–41,383,590, 42 genes, copy number 6 (within-gene range 4–6): COL9A2, AL031985.2, SMAP2, AL031985.1, AL031985.4, ZFP69B, AL031985.3, AL603839.4, ZFP69, AL603839.3, EXO5, AL603839.1, AL603839.2, ZNF684, AL356379.2, AL356379.1, GTF2F2P2, RIMS3, AL031289.2, AL031289.1, NFYC-AS1, NFYC, MIR30E, MIR30C1, KCNQ4, RN7SL326P, CITED4, AC119677.1, AL391730.1, AL391730.2, UBE2V1P8, CTPS1, SLFNL1-AS1, SLFNL1, SCMH1, RPL23AP17, AC093151.7, AC093151.2, AC093151.1, AC093151.5, FOXO6, FOXO6-AS1.
- chr1:83,575,776–111,768,000, 517 genes, copy number 5–7 (broad region; genes not listed).
- chr1:159,899,979–182,982,318, 530 genes, copy number 5–8 (broad region; genes not listed).
- chr2:53,470,447–75,199,520, 444 genes, copy number 5–6 (broad region; genes not listed).
- chr2:118,132,128–120,179,119, 20 genes, copy number 5 (within-gene range 3–5): THORLNC, LINC01956, EN1, MARCO, AC013457.1, C1QL2, RN7SL468P, STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5.
- chr3:12,153,068–15,142,157, 63 genes, copy number 6–11 (broad region; genes not listed).
- chr3:102,621,061–121,886,526, 270 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr3:127,165,506–140,980,995, 279 genes, copy number 5 (broad region; genes not listed).
- chr3:155,309,427–198,222,513, 763 genes, copy number 5–7 (broad region; genes not listed).
- chr4:53,377,839–54,740,715, 23 genes, copy number 5 (within-gene range 3–5): AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT.
- chr5:37,288,137–38,845,829, 28 genes, copy number 5 (within-gene range 2–5): NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1.
- chr5:97,504,663–98,995,013, 25 genes, copy number 7: LINC01340, MTCYBP40, AC112203.1, AC122697.1, LINC02234, AC008834.1, LINC01846, AC116347.1, PSME2P1, AC233964.1, KRT8P32, MRPS35P2, MTCO2P24, MTCO1P24, CTBP2P4, DDX18P4, RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P, LINC02062, Y_RNA, AC022121.1.
- chr7:70,972–3,302,452, 84 genes, copy number 6 (broad region; genes not listed).
- chr7:75,769,533–133,170,514, 986 genes, copy number 5–9 (broad region; genes not listed).
- chr7:133,290,881–133,315,413, 2 genes, copy number 5: MIR6133, AC083875.1.
- chr7:134,368,737–159,233,377, 597 genes, copy number 5–8 (broad region; genes not listed).
- chr8:123,288,355–145,066,685, 414 genes, copy number 6 (broad region; genes not listed).
- chr9:3,181,342–43,045,120, 731 genes, copy number 5 (broad region; genes not listed).
- chr10:24,848,614–24,952,606, 1 gene, copy number 5 (within-gene range 4–5): PRTFDC1.
- chr10:24,908,522–38,783,108, 261 genes, copy number 5–6 (broad region; genes not listed).
- chr10:49,014,236–55,746,908, 80 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:76,186,325–79,441,030, 73 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–32,072,880, 808 genes, copy number 6–8 (broad region; genes not listed).
- chr12:42,929,848–48,628,836, 131 genes, copy number 5 (broad region; genes not listed).
- chr14:32,934,396–38,987,383, 106 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr15:67,254,786–88,271,066, 553 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr16:75,838,576–77,660,570, 25 genes, copy number 5 (within-gene range 3–5): AC105430.1, RNA5SP430, AC099511.1, AC010528.1, RPL18P13, AC010528.2, CNTNAP4, AC106741.1, RN7SKP233, SNORD33, AC108125.1, LINC02125, AC106729.1, MIR4719, AC106734.1, AC106733.1, MON1B, SYCE1L, AC009139.2, VN2R10P, AC009139.1, ADAMTS18, AC025284.1, LINC02131, AC092724.1.
- chr17:3,896,592–4,143,030, 5 genes, copy number 5 (within-gene range 3–5): P2RX1, ATP2A3, LINC01975, ZZEF1, RNA5SP434.
- chr18:47,390–9,960,021, 206 genes, copy number 5 (broad region; genes not listed).
- chr19:53,854,581–58,605,223, 353 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr20:37,571,103–39,039,723, 51 genes, copy number 5: LINC01746, GLRXP1, LINC00489, AL162293.1, CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173, PPP1R16B, RN7SL116P, FAM83D, AL023803.2, AL023803.1, DHX35, AL023803.3, NPM1P19.
- chr21:10,328,411–25,717,562, 205 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr21:26,317,390–37,073,170, 245 genes, copy number 5–7 (within-gene range 5–9) (broad region; genes not listed).
- chr21:37,100,814–37,101,343, 1 gene, copy number 6: AP001429.1.
- chr22:24,594,811–24,629,005, 1 gene, copy number 5 (within-gene range 4–5): GGT1.
- chr22:24,632,915–26,031,045, 48 genes, copy number 5–8 (within-gene range 3–8): BCRP3, AP000356.4, AP000356.3, AP000356.2, POM121L10P, ARL5AP4, AP000357.1, AP000357.2, AP000358.1, CRIP1P4, PIWIL3, SGSM1, AL049759.1, TMEM211, KIAA1671, AL022323.2, AL022323.4, AL022323.1, AL022323.3, KIAA1671-AS1, Z99916.2, CRYBB3, Z99916.1, CRYBB2, Z99916.3, AL022332.1, AL022324.4, AL022332.2, IGLL3P, AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2, AL022329.1, GRK3, AL022329.2, YES1P1, RNA5SP494, MYO18B, AL022329.3, MYO18B-AS1, Z98949.2, RN7SKP169.
- chr22:35,703,803–40,044,530, 184 genes, copy number 5–7 (broad region; genes not listed).
- chr22:40,106,325–40,107,066, 1 gene, copy number 7: RPL7P52.

Autosomal genes at a single copy (total copy number 1): 4,211. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
